Somatic mutation profile of tumor specimen TCGA-EL-A3GZ-01A (aliquot TCGA-EL-A3GZ-01A-11D-A20C-08) from TCGA case TCGA-EL-A3GZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.7 years (12,665 days).
Specimen TCGA-EL-A3GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7bb88e6-be7a-498f-a9e2-846a319bf16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GZ-11A (Solid Tissue Normal), aliquot TCGA-EL-A3GZ-11A-11D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36cfbf09-2a42-46bc-8e36-182c31c0c0f0

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ELFN2 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV68744323, COSV68745131; called by muse, mutect2, varscan2
- H2BC4 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV58416668, COSV58417201; called by muse, mutect2, varscan2
- MSH2 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs376934727, COSV51881104, COSV99028408; called by muse, mutect2, varscan2
- MEX3A | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HTR3A | c.1344G>T p.V448= | Silent (SNP) | VAF 64/203 reads (32%) | catalogued as COSV55470262; called by muse, mutect2
- PODXL | c.576C>T p.P192= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV59870978; called by muse, mutect2, varscan2
